Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7314, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7314-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN NINE LYMPH NODES (0/9).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 4+3=7 WITH A TERTIARY GLEASON PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES 30% OF EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS EXTRACAPSULAR EXTENSION INTO THE PERIPROSTATIC ADIPOSE TISSUE IN THE REGIONS OF ANTERIOR RIGHT MID (SLIDE 3O), ANTERIOR RIGHT BASE (SLIDE 3P), POSTERIOR RIGHT MID (SLIDE 3W), POSTERIOR RIGHT BASE (SLIDE 3Y) AND POSTERIOR LEFT BASE (SLIDE 3CC).
- E. BILATERAL SEMINAL VESICLES ARE INVOLVED BY CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3b N0 MX.
- K. BACKGROUND PROSTATIC TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

PART 4: RIGHT PEDICLE MARGIN, EXCISION -

BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 6.1
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	39.38gm
TUMOR SIZE:	Maximum dimension: 2 cm

LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - NOS
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	14
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file a6312bdb-77e9-4e0e-aac0-cd51a1e00081 (TCGA-EJ-7314.BBD6FA31-F4D4-4C06-AA64-1E263CCD8844.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).